Somatic mutation profile of tumor specimen TCGA-09-2051-01A (aliquot TCGA-09-2051-01A-01W-0799-08) from TCGA case TCGA-09-2051, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.8 years (15,650 days).
Specimen TCGA-09-2051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87c77496-c2ce-46ad-ade6-823297c4ec0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2051-10A (Blood Derived Normal), aliquot TCGA-09-2051-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29a62a8-0455-48c5-90ae-947a7c00bfcc

The open-access MAF lists 145 somatic variants for this specimen: 117 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 27, Nonsense Mutation 7, Splice Site 6, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TG | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 352/1774 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912650, CM063181, COSV55069861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.6613G>T p.A2205S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.001); catalogued as COSV99804008; called by muse, varscan2
- ALG9 | c.1288G>T p.V430L (on ENST00000614444 / NM_001352418.1; = p.V437L on NM_024740.2) | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101211943; called by muse, mutect2
- ALMS1 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.268); catalogued as COSV100043478, COSV52508710; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4063G>T p.D1355Y | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99784294; called by muse, mutect2
- APLF | c.970T>G p.C324G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58143488; called by mutect2, varscan2
- ARHGEF37 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as COSV61370068; called by mutect2, varscan2
- CACNA1E | c.3055G>A p.V1019M | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs547399351, COSV62386021; called by muse, mutect2, varscan2
- CALML5 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV66702447; called by muse, mutect2, varscan2
- CCZ1B | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV100367997; called by muse, mutect2, varscan2
- CHD9 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 35/247 reads (14%) | catalogued as COSV68297481; called by muse, mutect2, varscan2
- CMSS1 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV70436045; called by muse, mutect2, varscan2
- CSE1L | c.1909G>T p.V637F | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53700858; called by muse, mutect2
- CSMD1 | c.3274C>A p.R1092S (on ENST00000520002; = p.R1091S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1480620459, COSV100153077, COSV59278782; called by muse, mutect2
- CSMD2 | c.397+2T>G p.X133_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV53891289; called by muse, mutect2, varscan2
- CX3CL1 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99136493; called by muse, mutect2, varscan2
- DDHD2 | c.1104G>T p.L368F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV68157491; called by muse, mutect2, varscan2
- DEFB126 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 19/727 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV101215704; called by muse, mutect2
- DMD | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as CM067370, COSV99925530; called by muse, mutect2
- DNAH1 | c.2761C>A p.L921I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV70227377; called by muse, mutect2, varscan2
- DNAH17 | c.10251G>T p.Q3417H | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101103270; called by muse, mutect2
- DNAH9 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 188/538 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52340441; called by muse, mutect2, varscan2
- DNTTIP1 | c.974C>A p.A325E | Missense Mutation (SNP) | VAF 28/870 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); catalogued as COSV99708760; called by muse, mutect2
- DRP2 | c.245_281+6del p.X82_splice | Splice Site (DEL) | VAF 93/150 reads (62%) | catalogued as COSV65809797; called by mutect2, pindel
- DST | c.17803A>G p.I5935V (on ENST00000361203 / NM_001374722.1; = p.I3632V on NM_015548.5) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.122); catalogued as COSV55004089; called by muse, mutect2, varscan2
- EBF3 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs866544665; called by muse, mutect2
- EDC4 | c.2578C>T p.R860* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as rs1265610875, COSV59302248; called by muse, mutect2, varscan2
- EDEM3 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.01); catalogued as COSV58922753; called by muse, mutect2, varscan2
- ENTPD1 | c.1349G>T p.W450L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100967726; called by muse, mutect2
- FBXO11 | c.1508G>A p.G503E (on ENST00000403359 / NM_001190274.2; = p.G419E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100319919; called by muse, varscan2
- FCGR2B | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 32/763 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99375365; called by muse, mutect2
- FGD6 | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 115/369 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs1412527809, COSV59691459; called by muse, mutect2, varscan2
- FLG2 | c.4772G>T p.R1591I | Missense Mutation (SNP) | VAF 96/2455 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV101166159, COSV66174369; called by muse, mutect2
- GCA | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV52025272; called by muse, mutect2, varscan2
- GNL3L | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.066); catalogued as rs1395849991, COSV100328579; called by muse, mutect2
- GOLGA4 | c.1943A>C p.K648T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV62709842; called by muse, mutect2, varscan2
- GSTM5 | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 184/590 reads (31%) | catalogued as COSV56657036, COSV56657991; called by muse, mutect2, varscan2
- HECTD4 | c.1266G>A p.W422* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV66388851; called by muse, mutect2, varscan2
- HERC2 | c.5173C>T p.R1725W | Missense Mutation (SNP) | VAF 132/422 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs776432681, COSV55314091; called by muse, varscan2
- HMCN1 | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 383/957 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54886510; called by muse, mutect2, varscan2
- HOXA7 | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99636732; called by muse, varscan2
- HYAL4 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV56137926; called by muse, mutect2, varscan2
- IL12A | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99975863; called by muse, mutect2
- INPP4A | c.1366C>G p.R456G | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50786928; called by muse, mutect2
- INVS | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 52/588 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV52439710; called by muse, mutect2
- KMT2D | c.16447G>T p.A5483S | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56454793, COSV99985415; called by muse, mutect2
- LIPI | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 61/452 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776761043, COSV60708335; called by muse, mutect2, varscan2
- LRRC36 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 99/156 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); catalogued as COSV52078727; called by muse, mutect2, varscan2
- LRRC8A | c.1165C>G p.R389G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52184759; called by muse, mutect2, varscan2
- LSM3 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1374497756, COSV99542586; called by muse, mutect2
- MC4R | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV55351633; called by muse, mutect2, varscan2
- MDN1 | c.13838T>A p.V4613D | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV65519013; called by muse, mutect2, varscan2
- MEFV | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534682649, COSV54821200; called by muse, mutect2
- MFSD2A | c.1568+2T>G p.X523_splice (on ENST00000372809 / NM_001136493.3; = p.X510_splice on NM_032793.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 110/296 reads (37%) | catalogued as rs112704028, COSV65685203; called by muse, mutect2, varscan2
- MGST1 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 197/1319 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV50566459; called by muse, mutect2, varscan2
- MROH5 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV101436117; called by muse, mutect2
- MROH6 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52783494; called by muse, mutect2, varscan2
- MYL4 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 85/109 reads (78%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV61698120; called by muse, mutect2, varscan2
- NCOA1 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56041200; called by muse, mutect2, varscan2
- NKX6-1 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 117/564 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV55684282; called by muse, mutect2, varscan2
- NNT | c.2756A>T p.D919V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV52923703; called by muse, mutect2, varscan2
- NXF1 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 303/474 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53672925; called by muse, mutect2, varscan2
- PCK1 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100100863; called by muse, mutect2
- PHF20 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 156/591 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs940529768, COSV100180667, COSV59187791; called by muse, mutect2, varscan2
- PLA2G12B | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 28/358 reads (8%) | catalogued as COSV100468312, COSV100468368; called by muse, mutect2
- PLCH1 | c.1367A>T p.E456V (on ENST00000340059 / NM_001130960.2; = p.E468V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/1033 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100398105; called by muse, mutect2, varscan2
- PLEKHG4B | c.2464C>T p.R822W (on ENST00000283426; = p.R1178W on NM_052909.5) | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149174138; called by muse, mutect2, varscan2
- POLR1A | c.2761C>A p.L921M | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99808316; called by muse, mutect2
- POLR2I | c.21C>G p.Y7* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as rs772329724, COSV52900093; called by muse, varscan2
- PPM1L | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 36/1382 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99862123; called by muse, mutect2
- PRKCQ | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 574/1090 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54108641; called by muse, mutect2, varscan2
- PTK7 | c.1657G>T p.G553W | Missense Mutation (SNP) | VAF 27/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100030568; called by muse, mutect2
- RAB2B | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99398563, COSV99398586; called by muse, mutect2
- RAD50 | c.2125C>A p.P709T | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99529518; called by muse, mutect2
- RARRES1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 93/821 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs375257995; called by muse, mutect2, varscan2
- RBBP7 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.303); catalogued as COSV58112635; called by muse, mutect2, varscan2
- RERE | c.969C>G p.N323K | Missense Mutation (SNP) | VAF 31/725 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as rs145265480, COSV100557214; called by muse, mutect2
- RESF1 | c.1166C>G p.A389G | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs748886668, COSV57020558; called by muse, varscan2
- RND1 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.894); catalogued as COSV59045021; called by muse, mutect2, varscan2
- RRP15 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs759583127, COSV65117524; called by muse, mutect2, varscan2
- SALL4 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as COSV53850680, COSV99409962; called by muse, mutect2, varscan2
- SAMD7 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV59417663; called by muse, mutect2, varscan2
- SCAP | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 143/199 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99653198; called by muse, mutect2, varscan2
- SLC1A6 | c.410T>G p.V137G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV99694165; called by muse, mutect2, varscan2
- SLC23A2 | c.1688G>A p.C563Y | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as COSV100595253; called by muse, mutect2
- SLC5A9 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99361936; called by muse, mutect2
- SPEN | c.8362G>C p.G2788R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as COSV65359357; called by muse, mutect2, varscan2
- SPTLC1 | c.561-1G>A p.X187_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | catalogued as COSV52763298; called by muse, mutect2, varscan2
- SRSF1 | c.420C>A p.H140Q | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51964424; called by muse, mutect2, varscan2
- ST8SIA1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 207/325 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV53952284; called by muse, mutect2, varscan2
- STAB1 | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV58733740; called by mutect2, varscan2
- STAT4 | c.1716-2A>G p.X572_splice | Splice Site (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100636160; called by muse, mutect2
- SYNE1 | c.13983C>A p.D4661E (on ENST00000367255 / NM_182961.4; = p.D4590E on NM_033071.3) | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99576490; called by muse, mutect2
- TANC1 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715029; called by muse, mutect2
- TMEM156 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV60744157; called by muse, mutect2, varscan2
- TNIK | c.3023G>A p.R1008K | Missense Mutation (SNP) | VAF 35/450 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV52677202; called by muse, mutect2
- TNKS1BP1 | c.2764G>T p.D922Y | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64100409; called by muse, mutect2, varscan2
- TRO | c.3328G>A p.G1110S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.103); catalogued as rs1205360536, COSV51502408; called by muse, varscan2
- TSEN2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs934468486, COSV99538857; called by muse, mutect2
- UNC79 | c.4010G>T p.C1337F (on ENST00000393151 / NM_001346218.2; = p.C1160F on NM_020818.5) | Missense Mutation (SNP) | VAF 45/941 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99829681; called by muse, mutect2
- USP48 | c.1738A>T p.N580Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57608227; called by muse, varscan2
- VNN1 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV63389545, COSV99057812; called by muse, mutect2
- XIRP2 | c.5444G>T p.W1815L (on ENST00000628543; = p.W1990L on NM_152381.6) | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs747794550, COSV54694579, COSV99746750; called by muse, mutect2
- ZBTB37 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62931747; called by muse, mutect2, varscan2
- ZKSCAN8 | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 126/440 reads (29%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.991); catalogued as rs1380332919, COSV100363018; called by muse, mutect2, varscan2
- ZNF549 | c.74G>T p.G25V (on ENST00000376233 / NM_001199295.2; = p.G12V on NM_153263.2) | Missense Mutation (SNP) | VAF 41/450 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs367783563; called by muse, mutect2
- ZZEF1 | c.5858G>C p.G1953A | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV67556433; called by muse, mutect2
- ATP1B2 | c.381_407del p.D127_Y135del | In Frame Del (DEL) | VAF 142/564 reads (25%) | called by mutect2, pindel
- EBF2 | c.439_440insT p.P147Lfs*15 | Frame Shift Ins (INS) | VAF 17/148 reads (11%) | called by mutect2, pindel*, varscan2
- EDC3 | c.355A>T p.K119* | Nonsense Mutation (SNP) | VAF 28/172 reads (16%) | called by mutect2, varscan2
- HDAC5 | c.2096_2107del p.G699_H702del | In Frame Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- IRAK1 | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCK2 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SYNPO | c.2542A>C p.K848Q (on ENST00000394243 / NM_001166208.2; = p.K604Q on NM_007286.6) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.117); called by mutect2, varscan2
- TENM2 | c.7957C>A p.Q2653K (on ENST00000518659 / NM_001122679.2; = p.Q2414K on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- TP53 | c.666_667del p.P223* | Frame Shift Del (DEL) | VAF 146/243 reads (60%) | called by mutect2, pindel, varscan2
- TXNDC5 | c.549del p.S183Rfs*104 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- ATG9A | c.504G>T p.L168= | Silent (SNP) | VAF 50/402 reads (12%) | catalogued as COSV100037173; called by muse, mutect2, varscan2
- CCDC136 | c.1449G>A p.E483= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52797629; called by muse, mutect2, varscan2
- CCDC40 | c.1269G>A p.K423= | Silent (SNP) | VAF 12/175 reads (7%) | catalogued as COSV99482174; called by muse, mutect2
- CCNB3 | c.936A>C p.A312= | Silent (SNP) | VAF 8/191 reads (4%) | catalogued as COSV99329727; called by muse, mutect2
- CELSR3 | c.1245C>A p.A415= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99374783; called by muse, mutect2
- DENND1A | c.936C>T p.F312= | Silent (SNP) | VAF 63/270 reads (23%) | catalogued as COSV101010775; called by mutect2, varscan2
- EBF3 | c.36G>T p.G12= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1395530304; called by mutect2, varscan2
- FGD1 | c.2382G>A p.G794= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100911242; called by muse, mutect2
- FLG | c.1827G>A p.S609= | Silent (SNP) | VAF 348/561 reads (62%) | catalogued as rs201705800; called by muse, mutect2, varscan2
- FRG2 | c.396G>A p.V132= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV66459679; called by muse, mutect2
- GALNT17 | c.513C>T p.S171= | Silent (SNP) | VAF 142/428 reads (33%) | catalogued as rs202215580, COSV61153408; called by muse, mutect2, varscan2
- GALNT6 | c.1203C>G p.P401= | Silent (SNP) | VAF 560/655 reads (85%) | catalogued as COSV62541853; called by muse, mutect2, varscan2
- GUCY2F | c.2682A>C p.T894= | Silent (SNP) | VAF 44/780 reads (6%) | catalogued as COSV99485566; called by muse, mutect2
- JMJD1C | c.957C>T p.S319= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as rs755964347, COSV67859338; called by muse, mutect2, varscan2
- KLK8 | c.729C>A p.T243= | Silent (SNP) | VAF 24/527 reads (5%) | catalogued as COSV99144075; called by muse, mutect2
- LRGUK | c.984C>T p.I328= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs770695122, COSV53635746; called by muse, mutect2, varscan2
- LRRC4B | c.471G>T p.L157= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100976028; called by muse, mutect2
- NLRC4 | c.1992C>A p.V664= | Silent (SNP) | VAF 26/665 reads (4%) | catalogued as COSV100707503; called by muse, mutect2
- OGDHL | c.1446C>T p.N482= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs762174983, COSV65101547; called by muse, mutect2, varscan2
- PTPRN | c.1014G>T p.L338= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV55346532; called by muse, varscan2
- RAB40AL | c.564G>A p.K188= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV54433764; called by muse, mutect2, varscan2
- RPS6KB1 | c.300G>C p.G100= | Silent (SNP) | VAF 338/2276 reads (15%) | catalogued as COSV99847722; called by muse, varscan2
- RSPH3 | c.126C>G p.P42= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV51921588; called by muse, mutect2, varscan2
- SELP | c.2343T>C p.S781= | Silent (SNP) | VAF 38/259 reads (15%) | catalogued as COSV55249715; called by muse, mutect2, varscan2
- SLC38A7 | c.621C>T p.S207= | Silent (SNP) | VAF 138/285 reads (48%) | catalogued as rs1451717749, COSV54702672, COSV54703190; called by muse, mutect2, varscan2
- TRO | c.3327C>T p.F1109= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs74903554, COSV51504237; called by muse, varscan2
- WDR75 | c.432C>G p.A144= | Silent (SNP) | VAF 56/251 reads (22%) | catalogued as rs751162375, COSV100134433; called by muse, mutect2, varscan2
- SNORD114-31 | n.69G>A | RNA (SNP) | VAF 73/97 reads (75%) | catalogued as rs771516408; called by muse, mutect2, varscan2
